Somatic mutation profile of tumor specimen TCGA-G4-6320-01A (aliquot TCGA-G4-6320-01A-11D-1719-10) from TCGA case TCGA-G4-6320, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage III; Age at diagnosis: 73.5 years (26,840 days).
Specimen TCGA-G4-6320-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30c38ffa-b359-4042-b6d7-11964ba2ab78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6320-10A (Blood Derived Normal), aliquot TCGA-G4-6320-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/407b4054-e7d5-46b5-974a-cb82c2517c89

The open-access MAF lists 1,226 somatic variants for this specimen: 920 protein-altering or splice-affecting, 282 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 706, Silent 282, Frame Shift Del 125, Nonsense Mutation 33, Frame Shift Ins 24, Splice Site 12, Intron 10, In Frame Del 9, Splice Region 7, RNA 5, 3'UTR 3, 5'Flank 3.

Variants (750 of 1,226; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6088C>T p.R2030* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as rs61751383, CM990071, COSV64674092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 97/234 reads (41%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012567148, CM1312460, COSV52431403; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/107 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MSH2 | c.1697del p.N566Ifs*24 | Frame Shift Del (DEL) | VAF 128/631 reads (20%) | catalogued as rs63750737, CM058387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYO3A | c.2180dup p.N727Kfs*9 | Frame Shift Ins (INS) | VAF 43/214 reads (20%) | catalogued as rs769462859; ClinVar: likely pathogenic; called by mutect2, varscan2
- SMARCB1 | c.983G>A p.R328Q (on ENST00000263121; = p.R374Q on NM_003073.5) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1057517825, CM1311945, COSV51954334, COSV51955761; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 31/232 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3532G>A p.D1178N (on ENST00000614293; = p.D1148N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55802269; called by muse, mutect2, varscan2
- ABCA2 | c.3227C>T p.S1076L (on ENST00000614293; = p.S1046L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369448216; called by muse, mutect2, varscan2
- ABCA6 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781051823, COSV52635635; called by muse, mutect2, varscan2
- ABCF1 | c.2461G>A p.D821N (on ENST00000326195 / NM_001025091.2; = p.D783N on NM_001090.3) | Missense Mutation (SNP) | VAF 109/486 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1254173922, COSV58229348; called by muse, mutect2, varscan2
- ABCF3 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs775630869, COSV53049929; called by muse, mutect2, varscan2
- ABI3BP | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1299717321, COSV52538470; called by muse, mutect2, varscan2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs756288275; called by mutect2, pindel
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 57/344 reads (17%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACSS3 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs776944932, COSV54092461; called by muse, mutect2, varscan2
- ADAM19 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.416); catalogued as COSV57431045; called by muse, mutect2, varscan2
- ADAM23 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs758258908, COSV52209251, COSV52215881; called by muse, mutect2, varscan2
- ADAM8 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs759368536, COSV101291604; called by muse, mutect2, varscan2
- ADAM8 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237124330, COSV69864750; called by muse, mutect2, varscan2
- ADAMTS2 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs149308698; called by muse, varscan2
- ADAMTS20 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV67132785; called by muse, mutect2, varscan2
- ADAMTS9 | c.4049G>A p.R1350Q | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs754078484, COSV55782512; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777446647, COSV52814008; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123dup p.Q1375Pfs*53 | Frame Shift Ins (INS) | VAF 37/192 reads (19%) | catalogued as rs758913277; called by mutect2, varscan2
- ADARB2 | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs950277767, COSV67224970; called by muse, mutect2, varscan2
- ADCY3 | c.3169C>T p.R1057W | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771914767, COSV53168093; called by muse, mutect2, varscan2
- ADCY7 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV99575663; called by muse, mutect2
- ADD1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs775330429, COSV53275200; called by muse, mutect2, varscan2
- ADGRV1 | c.15271del p.Y5091Tfs*7 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1435790810; called by mutect2, varscan2
- ADRA1D | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV65241079; called by muse, mutect2, varscan2
- AFF1 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV57120368; called by muse, mutect2, varscan2
- AFF3 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs368944733; called by muse, mutect2, varscan2
- AFM | c.35del p.F12Sfs*5 | Frame Shift Del (DEL) | VAF 47/304 reads (15%) | catalogued as rs1351383834; called by mutect2, pindel, varscan2
- AGPAT4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs1158616160, COSV57245733; called by muse, mutect2, varscan2
- AHNAK | c.10217C>A p.P3406H | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57215878; called by muse, mutect2, varscan2
- AHNAK2 | c.13486G>A p.D4496N | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs760149560, COSV60912529; called by muse, mutect2, varscan2
- AHR | c.1646_1649del p.D549Vfs*28 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | catalogued as COSV54123971; called by mutect2, pindel, varscan2
- AIDA | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 32/666 reads (5%) | catalogued as rs1220737314, COSV60664155; called by muse, mutect2
- AKAP9 | c.9781C>T p.R3261W (on ENST00000359028; = p.R3237W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs749167841, COSV62360743; called by muse, mutect2
- AKR7A3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 96/527 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs753968017, COSV100853789; called by muse, varscan2
- AKT3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55618493; called by muse, mutect2, varscan2
- ALDH1A1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52789918, COSV52793198; called by muse, mutect2
- ALDH6A1 | c.1256T>C p.F419S | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63246525; called by muse, mutect2, varscan2
- ALOX12B | c.1929G>A p.R643= | Splice Region (SNP) | VAF 23/69 reads (33%) | catalogued as rs775748631, COSV59873401, COSV59875139; called by muse, mutect2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, mutect2, varscan2
- ALS2CL | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs777220274, COSV59671776; called by muse, mutect2, varscan2
- ANGPTL8 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV52949063, COSV99371053; called by muse, mutect2, varscan2
- ANKAR | c.903A>C p.K301N | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV55613484, COSV55616480; called by muse, mutect2, varscan2
- ANKFN1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs751215331, COSV59440220; called by muse, mutect2, varscan2
- ANKFY1 | c.2995G>A p.A999T (on ENST00000341657 / NM_001330063.2; = p.A1000T on NM_016376.5) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747203838, COSV58918399; called by muse, mutect2, varscan2
- ANKS1A | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV64461206; called by muse, mutect2, varscan2
- ANO4 | c.2369C>T p.A790V (on ENST00000392977 / NM_001286615.2; = p.A755V on NM_178826.4) | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763712389, COSV100151981; called by muse, mutect2, varscan2
- ANO9 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765622452, COSV60383747; called by muse, mutect2, varscan2
- ANXA1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as rs533499971, COSV57411441; called by muse, mutect2, varscan2
- AP1M2 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs374637915; called by muse, varscan2
- APAF1 | c.676C>T p.R226C (on ENST00000551964 / NM_181861.2; = p.R215C on NM_001160.3) | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465434660, COSV59663669, COSV59664636; called by muse, mutect2, varscan2
- APBA1 | c.2311C>A p.L771I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55229215; called by muse, varscan2
- APOBEC3B | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs772434543, COSV59841181; called by muse, mutect2
- APOC4-APOC2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758859455, COSV52990451; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- ARAP1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs766090934, COSV61991554; called by muse, mutect2, varscan2
- ARAP2 | c.2877G>T p.E959D | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as COSV100394111; called by muse, mutect2
- ARAP2 | c.380T>A p.L127H | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.09); catalogued as COSV58287540; called by muse, mutect2, varscan2
- ARAP3 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs963954078, COSV53351021; called by muse, mutect2, varscan2
- ARFGEF1 | c.3815G>T p.R1272L | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51602906, COSV99141102; called by muse, mutect2
- ARHGAP31 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 16/315 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1332241306, COSV99956583; called by muse, mutect2
- ARHGEF10 | c.1990C>T p.R664C (on ENST00000398564; = p.R639C on NM_014629.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs751056745, COSV50653571; called by muse, mutect2, varscan2
- ARHGEF10L | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1238254004, COSV99391969; called by muse, mutect2
- ARHGEF12 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141324681; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARNT2 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV57586079; called by muse, varscan2
- ARNTL2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs952743145, COSV53826207; called by muse, mutect2, varscan2
- ASB7 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58403872; called by muse, mutect2, varscan2
- ASH1L | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV64208731; called by muse, mutect2, varscan2
- ASH1L | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV100853108; called by muse, mutect2
- ASTL | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV60904445; called by muse, mutect2, varscan2
- ATP11A | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as rs778305375, COSV52106701; called by muse, mutect2, varscan2
- ATP13A3 | c.3341del p.L1114Yfs*22 | Frame Shift Del (DEL) | VAF 66/361 reads (18%) | catalogued as COSV55469110; called by mutect2, pindel, varscan2
- ATP1A3 | c.688C>T p.R230C (on ENST00000545399 / NM_001256214.2; = p.R217C on NM_152296.5) | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782713179, COSV57488139; called by muse, mutect2, varscan2
- ATP6V1A | c.1494G>A p.K498= | Splice Region (SNP) | VAF 41/194 reads (21%) | catalogued as rs1222484984, COSV56362605; called by muse, mutect2, varscan2
- ATP8B3 | c.2335C>A p.L779M | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.897); catalogued as COSV100034022; called by muse, mutect2
- AVPR1A | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1405525372, COSV54546918; called by muse, mutect2, varscan2
- BACE2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV57740151; called by muse, mutect2
- BAZ2B | c.5759A>G p.Q1920R | Missense Mutation (SNP) | VAF 126/429 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58602135; called by muse, mutect2, varscan2
- BBS9 | c.2312C>T p.T771M (on ENST00000242067 / NM_001348036.1; = p.T731M on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as rs370662412; called by muse, mutect2, varscan2
- BCL3 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV51234312; called by muse, mutect2, varscan2
- BDKRB1 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV99387737; called by muse, mutect2
- BICD2 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778218322, COSV63549287; called by muse, mutect2, varscan2
- BICRA | c.2363G>T p.S788I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV67604978; called by muse, mutect2, varscan2
- BMP1 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs200556837, COSV60531373; called by muse, mutect2, varscan2
- BMPR1B | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs777745046, COSV52778395; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 32/200 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BNC1 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV100596903; called by muse, mutect2
- BRD1 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as rs751309590, COSV53456222; called by muse, mutect2, varscan2
- BRINP2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs755843993, COSV64175951; called by muse, mutect2, varscan2
- BRINP2 | c.2318C>A p.P773H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.094); catalogued as COSV64177863; called by muse, mutect2, varscan2
- BRINP3 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs752029342, COSV66511801; called by muse, mutect2, varscan2
- C10orf120 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61492087; called by muse, mutect2, varscan2
- C1orf122 | c.268dup p.Q90Pfs*70 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | catalogued as rs747134922; called by mutect2, varscan2
- C1orf35 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54342554; called by muse, mutect2, varscan2
- C2orf16 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV68646236, COSV68647244; called by muse, mutect2, varscan2
- CA3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as rs762494962, COSV53409184; called by muse, mutect2, varscan2
- CACHD1 | c.2269A>T p.R757* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as COSV51554251; called by muse, mutect2, varscan2
- CACNA1B | c.5375C>T p.T1792M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1284463864, COSV53128141; called by muse, mutect2, varscan2
- CACNB2 | c.1880G>A p.R627H (on ENST00000324631 / NM_201596.3; = p.R572H on NM_000724.4) | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as rs758934103, COSV56627222; called by muse, mutect2, varscan2
- CAD | c.5659G>T p.G1887C | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV53027642; called by muse, mutect2, varscan2
- CALCOCO1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV50414604; called by muse, mutect2, varscan2
- CAMTA1 | c.4767del p.K1589Nfs*33 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | catalogued as rs754008719; called by mutect2, varscan2
- CAPN12 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1340448856, COSV100184989; called by muse, mutect2, varscan2
- CASKIN1 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100623808; called by muse, varscan2
- CASKIN2 | c.2786C>T p.T929M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs775974159, COSV58596349, COSV58597683; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | catalogued as COSV100050703; called by mutect2, pindel, varscan2
- CATSPERE | c.1673A>G p.D558G | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100834902; called by muse, varscan2
- CBFA2T3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs758562596, COSV51927785; called by muse, mutect2, varscan2
- CBX1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV56681987, COSV56682228; called by muse, mutect2, varscan2
- CC2D1A | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745708547, COSV58783852; called by muse, mutect2, varscan2
- CCDC15 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61081425; called by muse, mutect2, varscan2
- CCDC151 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as rs911990764, COSV62698136; called by muse, mutect2
- CCDC180 | c.1659C>T p.S553= | Splice Region (SNP) | VAF 7/69 reads (10%) | catalogued as COSV63831094; called by muse, mutect2, varscan2
- CCDC39 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV56485525; called by muse, mutect2, varscan2
- CCDC85A | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs921834802, COSV68151614; called by muse, mutect2, varscan2
- CCDC9 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs951060044, COSV99699931; called by muse, mutect2
- CCNJ | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs1488931381, COSV99796155; called by muse, mutect2, varscan2
- CCT8L2 | c.1401G>C p.M467I | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV63462749; called by muse, mutect2, varscan2
- CDAN1 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62332350; called by muse, mutect2
- CDC16 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 73/470 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs765036454, COSV99372705; called by muse, mutect2, varscan2
- CDK11B | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 96/712 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs778552932, COSV100477256; called by muse, varscan2
- CDO1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99164750; called by mutect2, varscan2
- CEL | c.40C>A p.L14I (on ENST00000673714; = p.L11I on NM_001807.6) | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV59600239; called by muse, mutect2, varscan2
- CEP89 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 85/420 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs773793137, COSV59864775; called by muse, mutect2, varscan2
- CERS6 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59830894; called by muse, mutect2, varscan2
- CFAP20DC | c.1040C>T p.P347L (on ENST00000482387 / NM_001351530.2; = p.P222L on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs141916956, COSV55920191; called by muse, varscan2
- CFLAR | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs955193277, COSV100010005; called by muse, mutect2
- CFP | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55950420; called by muse, mutect2, varscan2
- CGA | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63644504; called by muse, varscan2
- CHD3 | c.1206C>A p.H402Q | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57875908; called by muse, mutect2, varscan2
- CHD4 | c.3409C>T p.P1137S (on ENST00000357008 / NM_001363606.2; = p.P1150S on NM_001273.5) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58902451; called by muse, mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 67/338 reads (20%) | catalogued as rs748826986; called by mutect2, varscan2
- CHEK2 | c.668G>A p.R223H (on ENST00000382580 / NM_001005735.2; = p.R180H on NM_007194.4) | Missense Mutation (SNP) | VAF 138/528 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs137853009, CM030418, COSV60417374; ClinVar: conflicting interpretations of pathogenicity / pathogenic / uncertain significance; called by muse, varscan2
- CHL1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs752378415, COSV56595004, COSV99851945; called by muse, mutect2, varscan2
- CHRM3 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55090938; called by muse, mutect2, varscan2
- CLCA4 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1039479646, COSV55368547; called by muse, mutect2
- CLEC10A | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs368746225, COSV54700715; called by muse, mutect2, varscan2
- CLEC2B | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57309734; called by muse, mutect2, varscan2
- CLEC4F | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV55479754, COSV55479863; called by muse, mutect2, varscan2
- CMIP | c.2110C>T p.R704W (on ENST00000537098 / NM_198390.2; = p.R610W on NM_030629.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV67698625; called by muse, mutect2, varscan2
- CNOT11 | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as rs750783059, COSV56820039; called by muse, mutect2, varscan2
- CNTN1 | c.2998C>A p.P1000T | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV61640507; called by muse, mutect2, varscan2
- CNTN3 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99723278; called by muse, mutect2, varscan2
- CNTN6 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV63174513; called by muse, mutect2, varscan2
- COA6 | c.181del p.A61Pfs*9 | Frame Shift Del (DEL) | VAF 28/129 reads (22%) | catalogued as rs1161604507; called by mutect2, pindel, varscan2
- COG4 | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs767599010, COSV55371525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.1635dup p.P546Afs*9 | Frame Shift Ins (INS) | VAF 155/675 reads (23%) | catalogued as rs779795373; called by mutect2, varscan2
- COL16A1 | c.3726G>A p.P1242= | Splice Region (SNP) | VAF 33/147 reads (22%) | catalogued as rs374986257; called by muse, mutect2, varscan2
- COL16A1 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54707179; called by muse, mutect2, varscan2
- COL16A1 | c.1356del p.G453Afs*8 | Frame Shift Del (DEL) | VAF 44/202 reads (22%) | catalogued as rs752762639, COSV54713124; called by mutect2, pindel, varscan2
- COL17A1 | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100793044; called by muse, mutect2, varscan2
- COL1A1 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.294); catalogued as COSV56805897; called by muse, mutect2
- COL21A1 | c.1110T>G p.I370M | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV55165370; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 11/58 reads (19%) | catalogued as rs760493024; called by mutect2, varscan2
- COL2A1 | c.4112C>T p.A1371V | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.16); catalogued as COSV100475476, COSV61534583; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- COL5A1 | c.4528G>A p.G1510S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65669748; called by muse, mutect2, varscan2
- CORO1C | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs889648907, COSV54596356; called by muse, mutect2, varscan2
- CPEB2 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99469909; called by muse, mutect2
- CPNE7 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs533420972, COSV52013239; called by muse, mutect2, varscan2
- CPS1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV51812208; called by muse, mutect2, varscan2
- CREB3L1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs749140671, COSV55831599; called by muse, mutect2, varscan2
- CREBZF | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99476105; called by muse, mutect2, varscan2
- CST2 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs749218618, COSV100491113; called by muse, mutect2, varscan2
- CTNND2 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 53/456 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs745370714, COSV58893678; called by muse, mutect2, varscan2
- CTSH | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs1236795859, COSV54985286; called by muse, mutect2, varscan2
- CTU2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as rs562321109, COSV56338239; called by muse, mutect2, varscan2
- CUL9 | c.2941G>A p.V981M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs374241248; called by muse, mutect2, varscan2
- CUX2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs748957015, COSV55650390; called by muse, mutect2, varscan2
- CWC25 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 106/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747411602; called by muse, mutect2, varscan2
- CYBA | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868210009, COSV99879746; called by muse, varscan2
- CYP7B1 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV59589691; called by muse, mutect2, varscan2
- DAAM2 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767650659, COSV51330367; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs751187768; called by mutect2, varscan2
- DACH1 | c.487A>T p.S163C | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV57502855; called by muse, varscan2
- DAPK1 | c.3418T>C p.F1140L | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100801023; called by muse, mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 16/93 reads (17%) | catalogued as rs782606429; called by mutect2, varscan2
- DCAF5 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58460764; called by muse, mutect2, varscan2
- DCHS1 | c.6905A>G p.D2302G | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201483; called by muse, mutect2
- DCTN2 | c.227C>A p.T76N (on ENST00000548249 / NM_001261413.2; = p.T81N on NM_006400.4) | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV71553158; called by muse, varscan2
- DDX31 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64649797; called by muse, mutect2, varscan2
- DDX53 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV60069233; called by muse, mutect2, varscan2
- DDX54 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs775434731, COSV58373907; called by muse, mutect2, varscan2
- DDX58 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101152455; called by muse, mutect2, varscan2
- DEGS1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV60379390; called by muse, mutect2, varscan2
- DENND4B | c.3308G>A p.R1103H | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs202061696, COSV63409598; called by muse, mutect2, varscan2
- DGKZ | c.1036C>T p.R346C (on ENST00000454345 / NM_001105540.2; = p.R158C on NM_003646.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV58989437; called by muse, mutect2, varscan2
- DHX15 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as rs940594772, COSV61025614; called by muse, mutect2
- DHX58 | c.1960C>A p.R654S | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99288005; called by muse, mutect2, varscan2
- DIAPH2 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 172/570 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV61272341; called by muse, mutect2, varscan2
- DIAPH2 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 26/732 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs1334461463, COSV61298487; called by muse, mutect2
- DIRAS1 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV60215251, COSV60215762; called by muse, mutect2, varscan2
- DISP3 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs368871244; called by muse, mutect2, varscan2
- DLG4 | c.1000G>A p.E334K (on ENST00000399506 / NM_001321075.3; = p.E377K on NM_001365.4) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57239136; called by muse, mutect2, varscan2
- DMRT3 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as rs149469082; called by muse, mutect2, varscan2
- DNAH11 | c.3310G>T p.V1104L | Missense Mutation (SNP) | VAF 74/550 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV60959109; called by muse, varscan2
- DNAH11 | c.3390G>T p.M1130I | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV60959121; called by muse, varscan2
- DNAH2 | c.7252G>A p.V2418M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377358825; called by muse, mutect2, varscan2
- DNAJB7 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 124/680 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs751714280, COSV53422054; called by muse, mutect2, varscan2
- DNAJC6 | c.2124C>A p.S708R | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV54776004; called by muse, mutect2, varscan2
- DOCK4 | c.3400A>T p.I1134F | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV69854681; called by muse, mutect2, varscan2
- DOCK4 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375668683; called by muse, mutect2, varscan2
- DOCK6 | c.5912G>A p.R1971Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs761608003, COSV53915863; called by muse, mutect2, varscan2
- DOCK6 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as rs189925805; called by muse, mutect2, varscan2
- DOCK7 | c.1419del p.F473Lfs*8 | Frame Shift Del (DEL) | VAF 28/172 reads (16%) | catalogued as rs1557822062, COSV51995102; called by mutect2, varscan2
- DOP1B | c.2407T>C p.C803R | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV67693661; called by muse, mutect2, varscan2
- DPEP2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs761580112, COSV52054791; called by muse, mutect2, varscan2
- DPY19L2 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100116520; called by muse, mutect2, varscan2
- DRD2 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60759136; called by muse, mutect2, varscan2
- DSCAM | c.5177C>T p.P1726L | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs994959581, COSV68020097; called by muse, mutect2, varscan2
- DST | c.22028G>A p.R7343Q (on ENST00000361203 / NM_001374722.1; = p.R5053Q on NM_015548.5) | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs372639720, COSV55013488; called by muse, mutect2, varscan2
- DTWD1 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 170/559 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52071909; called by muse, mutect2, varscan2
- DUS3L | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049218368, COSV57832150; called by muse, mutect2, varscan2
- DUSP4 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV53546249; called by muse, mutect2
- DYRK1B | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as rs753581092, COSV59913874; called by muse, mutect2, varscan2
- ECD | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1254478699, COSV100624677; called by muse, mutect2
- EFCAB5 | c.67_68del p.R23Efs*6 | Frame Shift Del (DEL) | VAF 74/344 reads (22%) | catalogued as rs1316561427; called by pindel, varscan2
- EFCAB6 | c.999A>G p.I333M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53064773; called by muse, mutect2, varscan2
- EFNA1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548758015, COSV57596353; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF2AK4 | c.2319+9_2319+10dup p.X773_splice | Splice Site (INS) | VAF 18/92 reads (20%) | catalogued as rs56315322; called by mutect2, varscan2
- ELL | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99442768; called by muse, mutect2, varscan2
- ELOA2 | c.1295C>A p.P432H | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV55296734, COSV99795905; called by muse, mutect2
- ELP6 | c.771del p.F257Lfs*29 | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | catalogued as rs1424616187; called by mutect2, pindel, varscan2
- EMX2 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV71294645; called by muse, mutect2, varscan2
- ENAM | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV68536104; called by muse, mutect2, varscan2
- ENOX1 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54901689; called by muse, mutect2, varscan2
- ENPP1 | c.740del p.N247Tfs*2 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | catalogued as rs759257042, COSV100719662; called by mutect2, pindel, varscan2
- ENTPD6 | c.674-2A>G p.X225_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100736977; called by muse, mutect2, varscan2
- ENTPD8 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs781012598, COSV58162155; called by muse, mutect2, varscan2
- EP400 | c.7082A>T p.H2361L | Missense Mutation (SNP) | VAF 95/430 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57774362; called by muse, mutect2, varscan2
- EPHA5 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56648913; called by muse, mutect2, varscan2
- EPHA8 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776511588, COSV51268352; called by muse, mutect2, varscan2
- ERBB3 | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV57255166, COSV99031610; called by muse, mutect2, varscan2
- ERBB4 | c.3060G>T p.E1020D | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV61493085; called by muse, mutect2, varscan2
- EXO1 | c.174T>A p.F58L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100799614; called by muse, mutect2
- EXOC4 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV54101477, COSV54119545; called by muse, mutect2, varscan2
- EXOG | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | catalogued as rs756034502, COSV55063533; called by muse, mutect2, varscan2
- EXT1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1317388728, COSV65480282; called by muse, mutect2, varscan2
- EZH2 | c.1760C>T p.T587I (on ENST00000460911 / NM_001203247.2; = p.T592I on NM_004456.5) | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100234773, COSV57449025; called by muse, mutect2
- F7 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.229); catalogued as COSV100660942; called by muse, mutect2, varscan2
- F8 | c.5000G>A p.R1667Q | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs782342540, COSV64271614; called by muse, mutect2
- FAM187B | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61201329; called by muse, mutect2, varscan2
- FAM189B | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); catalogued as rs1279219258, COSV56945508; called by muse, mutect2, varscan2
- FAM81A | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406302088, COSV55678307; called by muse, mutect2, varscan2
- FAM81B | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs201358737, COSV51983409; called by muse, mutect2, varscan2
- FANCA | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs761957732, COSV101224667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCG | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62720803; called by muse, mutect2, varscan2
- FARSA | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375272364, COSV58905075; called by muse, mutect2, varscan2
- FASN | c.4634G>A p.R1545H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as rs41283363, COSV60755814; called by muse, mutect2, varscan2
- FAT4 | c.13355C>T p.T4452I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100627229; called by muse, mutect2
- FBN1 | c.7379A>T p.K2460I | Missense Mutation (SNP) | VAF 163/561 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as CM077246, COSV57318822; called by muse, mutect2, varscan2
- FBN3 | c.4280G>A p.R1427H | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs201734734, COSV99559808; called by muse, mutect2, varscan2
- FBRS | c.1180C>T p.R394C (on ENST00000287468; = p.R914C on NM_001105079.3) | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs771113657, COSV54916532; called by muse, mutect2, varscan2
- FBXO10 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs776126565, COSV52833356; called by muse, mutect2, varscan2
- FBXO10 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52833366; called by muse, mutect2, varscan2
- FCGBP | c.4951C>T p.R1651W | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1224971387, COSV99660911; called by muse, varscan2
- FCRL3 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs781010547, COSV63842044; called by muse, mutect2, varscan2
- FGF14 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 159/809 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV65945068; called by muse, mutect2, varscan2
- FGF8 | c.269G>A p.R90H (on ENST00000344255 / NM_033164.4; = p.R72H on NM_006119.6) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1445221357, COSV60142205; called by muse, mutect2, varscan2
- FH | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM068225, COSV100844977; called by muse, varscan2
- FIG4 | c.2326T>A p.S776T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs1339498922, COSV57788152; called by muse, mutect2, varscan2
- FLT4 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56110735; called by muse, mutect2, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs755445139; called by mutect2, varscan2
- FNDC1 | c.4327dup p.T1443Nfs*81 | Frame Shift Ins (INS) | VAF 28/150 reads (19%) | catalogued as rs1410233255; called by mutect2, varscan2
- FOXE1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64300793; called by muse, mutect2, varscan2
- FRG2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 86/360 reads (24%) | catalogued as COSV66459881; called by muse, mutect2, varscan2
- FRMPD3 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs775299172, COSV52191235; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | catalogued as rs777471402; called by mutect2, varscan2
- GABRG2 | c.1267C>T p.R423C (on ENST00000361925 / NM_001375343.1; = p.R383C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768576864, COSV62716095, COSV62717375, COSV62718640; called by muse, mutect2, varscan2
- GABRR1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs376401079; called by muse, varscan2
- GAL3ST3 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs1483491370, COSV100360890, COSV61749940; called by muse, mutect2, varscan2
- GALNT10 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1455800951, COSV51726789; called by muse, mutect2, varscan2
- GALT | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM108440, COSV66593016; called by muse, mutect2, varscan2
- GARRE1 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs373093362, COSV55099900; called by muse, mutect2, varscan2
- GCNA | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV101031539, COSV65461948; called by muse, mutect2
- GFPT1 | c.1819G>A p.V607M (on ENST00000357308 / NM_001244710.2; = p.V589M on NM_002056.4) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61948254; called by muse, mutect2, varscan2
- GGT5 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99571255; called by muse, mutect2, varscan2
- GGTLC1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 141/524 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs1374965182, COSV53848364; called by muse, mutect2, varscan2
- GIMAP8 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56231846; called by muse, mutect2, varscan2
- GIPR | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV54424335; called by muse, mutect2, varscan2
- GLT6D1 | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65627823; called by muse, mutect2, varscan2
- GLYATL1 | c.563G>A p.R188Q (on ENST00000317391 / NM_001354699.1; = p.R219Q on NM_080661.4) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs746647261, COSV55607200; called by muse, mutect2, varscan2
- GLYCTK | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs761902954, COSV59793927; called by muse, mutect2, varscan2
- GNA15 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV53586359; called by muse, mutect2, varscan2
- GNAO1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as CM161438, COSV52615065; called by muse, varscan2
- GNAZ | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.918); catalogued as COSV50738600; called by muse, mutect2, varscan2
- GPER1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52469249; called by muse, mutect2, varscan2
- GPR179 | c.1741G>A p.A581T (on ENST00000621958; = p.A580T on NM_001004334.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239866129; called by muse, mutect2, varscan2
- GRAMD1B | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs780877280, COSV59205493; called by muse, mutect2, varscan2
- GRIA4 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 39/156 reads (25%) | catalogued as COSV56899720; called by muse, mutect2, varscan2
- GRIK4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as rs1346610064, COSV70800248; called by muse, mutect2, varscan2
- GRM1 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51160828, COSV51238188; called by muse, mutect2, varscan2
- GRM5 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59596232, COSV59608030; called by muse, mutect2, varscan2
- GRM7 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 74/250 reads (30%) | catalogued as COSV100735674; called by mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2A1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 147/521 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.454); catalogued as COSV99993309; called by muse, mutect2, varscan2
- GTF3C2 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV99272155; called by muse, mutect2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- H3-4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs545672641, COSV64210693; called by muse, mutect2, varscan2
- H3C2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52518947; called by muse, mutect2, varscan2
- HASPIN | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs150287837; called by muse, mutect2, varscan2
- HBG1 | c.316-1G>A p.X106_splice | Splice Site (SNP) | VAF 33/212 reads (16%) | catalogued as COSV100400564; called by muse, mutect2, varscan2
- HDHD5 | c.998C>T p.T333M (on ENST00000336737 / NM_033070.3; = p.T303M on NM_017829.5) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs773813838, COSV50086624; called by muse, mutect2, varscan2
- HECW1 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV67831060; called by muse, mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HERC2 | c.6817C>A p.L2273M | Missense Mutation (SNP) | VAF 125/611 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.979); catalogued as COSV55327113; called by muse, mutect2, varscan2
- HIF3A | c.1996G>A p.A666T (on ENST00000377670 / NM_152795.4; = p.A597T on NM_022462.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV99743920; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPUL1 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54562778; called by muse, mutect2, varscan2
- HOMER2 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV100420173; called by muse, mutect2
- HOXB2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs528498436, COSV57485655; called by muse, mutect2, varscan2
- HPS6 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs373272174; called by muse, mutect2, varscan2
- HSP90AB1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62334904; called by muse, mutect2, varscan2
- HSPG2 | c.7843G>A p.V2615I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as rs142226974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUNK | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1233392236, COSV54229194; called by muse, mutect2, varscan2
- IFI35 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.397); catalogued as rs374815335, COSV55896425; called by muse, mutect2, varscan2
- IGF2R | c.3464T>C p.V1155A | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100806900; called by muse, mutect2, varscan2
- IGLON5 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.746); catalogued as rs779810845, COSV54536211, COSV54536292; called by muse, mutect2, varscan2
- IGSF10 | c.7208G>A p.R2403Q | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs753363334, COSV56373230, COSV56381094; called by muse, mutect2, varscan2
- IGSF9 | c.3485G>A p.R1162Q (on ENST00000368094 / NM_001135050.2; = p.R1146Q on NM_020789.4) | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs745423827, COSV57422473; called by muse, mutect2, varscan2
- IHH | c.1135del p.E379Rfs*18 | Frame Shift Del (DEL) | VAF 32/176 reads (18%) | catalogued as COSV55393105; called by mutect2, pindel, varscan2
- IL17C | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs765770314, COSV54918470, COSV54918650; called by muse, mutect2, varscan2
- ING1 | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV58169653; called by muse, mutect2
- INSYN1 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65837473; called by muse, mutect2, varscan2
- INTS6 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100246884; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs761880048; called by mutect2, varscan2
- ITCH | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767950508, COSV52932745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA2B | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs764585011, COSV52232838; called by muse, mutect2, varscan2
- ITGB4 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52326923; called by muse, mutect2
- ITGB4 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs772928070, COSV52326935; called by muse, mutect2, varscan2
- ITPR1 | c.3578C>T p.A1193V (on ENST00000354582; = p.A1178V on NM_002222.7) | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100229554; called by muse, mutect2, varscan2
- ITPR3 | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1049190814, COSV65410295; called by muse, mutect2, varscan2
- ITSN2 | c.3541G>A p.V1181I | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as rs755203715, COSV61945813; called by muse, mutect2, varscan2
- JHY | c.2332G>A p.V778I | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs745355947, COSV57075835; called by muse, mutect2, varscan2
- JPH1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1482597158, COSV60611522; called by muse, mutect2, varscan2
- KATNAL1 | c.1448G>T p.W483L | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66063458; called by muse, mutect2, varscan2
- KBTBD4 | c.1156dup p.E386Gfs*4 | Frame Shift Ins (INS) | VAF 51/276 reads (18%) | catalogued as rs756343868, COSV58597480; called by mutect2, varscan2
- KCNAB2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as rs143302486; called by muse, mutect2, varscan2
- KCND3 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs760274429, COSV56181897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNG2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1267698576, COSV60267923; called by muse, mutect2
- KCNH4 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1285947462, COSV99236749; called by muse, mutect2, varscan2
- KDM2A | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1237813567, COSV67082305; called by muse, mutect2, varscan2
- KDM7A | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 91/724 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV50091964; called by muse, mutect2, varscan2
- KHSRP | c.1223C>G p.P408R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.053); catalogued as COSV101231174, COSV67919792; called by muse, mutect2, varscan2
- KIAA0319 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100985197; called by muse, varscan2
- KIF20A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781453282, COSV67509946; called by muse, mutect2, varscan2
- KIF21A | c.806A>T p.K269M | Missense Mutation (SNP) | VAF 66/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62772321; called by muse, mutect2, varscan2
- KIF26B | c.3646G>A p.D1216N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs766451582, COSV63642877; called by muse, mutect2, varscan2
- KIFC3 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782226613, COSV65550191; called by muse, mutect2
- KIR3DL1 | c.779del p.G260Efs*83 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | catalogued as rs748477568; called by mutect2, pindel, varscan2
- KLF17 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs773530149, COSV100954795, COSV64856420; called by muse, mutect2, varscan2
- KLF4 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65929017, COSV65929878; called by muse, mutect2, varscan2
- KLHL23 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV55867540; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.7973A>G p.N2658S | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99494905, COSV99495536; called by muse, mutect2, varscan2
- KMT2D | c.10178C>T p.P3393L | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754209328, COSV56447953; called by muse, mutect2, varscan2
- KNDC1 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs746028459, COSV58838810; called by muse, mutect2, varscan2
- KPRP | c.1019del p.P340Hfs*31 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as COSV100908727; called by mutect2, pindel, varscan2
- KRT14 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1453932367; called by muse, mutect2
- KRT31 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs141617467; called by muse, mutect2, varscan2
- KRT4 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs556920531, COSV53406944; called by muse, mutect2, varscan2
- KRT79 | c.1486del p.A496Pfs*43 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs746321620; called by mutect2, pindel, varscan2
- KRT82 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748105910, COSV57786187; called by muse, mutect2, varscan2
- LAD1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs754757676, COSV66212629; called by muse, mutect2, varscan2
- LAMA5 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220052194, COSV53361501; called by muse, varscan2
- LARGE2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770017268, COSV57654841; called by muse, mutect2
- LATS2 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66876384; called by muse, mutect2, varscan2
- LCE2B | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as COSV100909278; called by muse, mutect2, varscan2
- LDOC1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65159356; called by muse, varscan2
- LINGO2 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58058588; called by muse, mutect2
- LMO7 | c.3734G>T p.W1245L (on ENST00000357063; = p.W926L on NM_005358.5) | Missense Mutation (SNP) | VAF 130/1104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58538452; called by muse, mutect2, varscan2
- LRP1 | c.12527G>A p.R4176Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs766010228, COSV54513712; called by muse, mutect2, varscan2
- LRP10 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV62078381; called by muse, mutect2, varscan2
- LRP1B | c.13433G>T p.R4478I | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101252540; called by muse, mutect2, varscan2
- LRP1B | c.1991G>T p.W664L | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101252543, COSV101261383; called by muse, mutect2, varscan2
- LRRC28 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV57338671; called by muse, mutect2, varscan2
- LRRC47 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs141393641; called by muse, mutect2, varscan2
- LRRC66 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 148/347 reads (43%) | catalogued as COSV58634312; called by muse, mutect2, varscan2
- LRRC7 | c.3120G>T p.M1040I (on ENST00000651989 / NM_001370785.2; = p.M1007I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50471799; called by muse, mutect2, varscan2
- LYZL1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs766725731, COSV64966156; called by muse, mutect2, varscan2
- LZTS1 | c.1295G>T p.R432M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV56117113; called by muse, mutect2, varscan2
- MACF1 | c.20363C>T p.T6788M (on ENST00000372915; = p.T4833M on NM_012090.5) | Missense Mutation (SNP) | VAF 65/314 reads (21%) | catalogued as rs180745507, COSV57124625; called by muse, mutect2, varscan2
- MADD | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194787525, CM124545, COSV60624917; called by muse, mutect2, varscan2
- MAGEC1 | c.2502C>A p.F834L | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.011); catalogued as COSV53573935, COSV53584376; called by muse, mutect2, varscan2
- MAGI2 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.97); catalogued as COSV100832839; called by muse, mutect2, varscan2
- MAN2A1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 36/810 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV99810429; called by muse, mutect2
- MAP1S | c.2363G>A p.S788N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1247495629, COSV60722927; called by muse, mutect2, varscan2
- MAP4K2 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs374778757; called by muse, mutect2, varscan2
- MASP2 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68896787, COSV68897747; called by muse, mutect2, varscan2
- MASTL | c.2162G>A p.R721Q (on ENST00000375940 / NM_001372029.1; = p.R720Q on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781161589, COSV60911115; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs762648935; called by pindel, varscan2
- MCF2L | c.2666G>A p.S889N (on ENST00000375608; = p.S857N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766123730, COSV56178454; called by muse, mutect2, varscan2
- MCUB | c.695del p.G232Vfs*37 | Frame Shift Del (DEL) | VAF 97/426 reads (23%) | catalogued as COSV99488674; called by mutect2, pindel, varscan2
- MDC1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 193/451 reads (43%) | catalogued as rs1562095881, COSV64524952; called by muse, mutect2, varscan2
- MDGA1 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1476295304, COSV51796668, COSV51799769; called by muse, mutect2, varscan2
- MDN1 | c.5602C>T p.Q1868* | Nonsense Mutation (SNP) | VAF 54/221 reads (24%) | catalogued as COSV101020767; called by muse, mutect2, varscan2
- MED12L | c.1779G>T p.K593N | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs747740641, COSV99851537; called by muse, mutect2, varscan2
- MEGF8 | c.3208G>A p.A1070T (on ENST00000251268 / NM_001271938.2; = p.A1003T on NM_001410.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs772370974, COSV52087511; called by muse, mutect2, varscan2
- MGAT3 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57864250; called by muse, mutect2, varscan2
- MGAT5 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.072); catalogued as rs138982519; called by muse, mutect2, varscan2
- MIGA2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs752697058, COSV52977193; called by muse, mutect2, varscan2
- MIP | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748257915, COSV57509233, COSV57512028; called by muse, mutect2, varscan2
- MMD2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747597869, COSV68660548; called by muse, mutect2
- MOV10L1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs758159949, COSV53172972; called by muse, mutect2, varscan2
- MTA2 | c.1698del p.A568Qfs*29 | Frame Shift Del (DEL) | VAF 43/217 reads (20%) | catalogued as COSV53470322; called by mutect2, pindel, varscan2
- MTIF3 | c.624_626del p.I209del | In Frame Del (DEL) | VAF 47/277 reads (17%) | catalogued as COSV63528597; called by mutect2, pindel, varscan2
- MTOR | c.3234G>A p.M1078I | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs757645678, COSV63872370; called by muse, mutect2, varscan2
- MTR | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1410795354, COSV100855169; called by muse, mutect2
- MTRF1L | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 181/898 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1216613841, COSV65873485; called by muse, mutect2, varscan2
- MUC16 | c.39760C>T p.Q13254* | Nonsense Mutation (SNP) | VAF 56/398 reads (14%) | catalogued as rs1449404465, COSV66692782; called by muse, mutect2, varscan2
- MUC2 | c.2260G>A p.V754M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.08); catalogued as rs776041994; called by muse, mutect2, varscan2
- MUC5B | c.9344C>T p.T3115M | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs563537111, COSV71591530; called by muse, mutect2, varscan2
- MVD | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55368483; called by muse, mutect2, varscan2
- MXRA5 | c.4822G>A p.V1608I | Missense Mutation (SNP) | VAF 146/377 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs867630637, COSV54237746; called by muse, mutect2, varscan2
- MYBBP1A | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV54598386; called by muse, mutect2, varscan2
- MYBPC3 | c.1358del p.P453Lfs*13 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | catalogued as CD034631, CD1412241; called by mutect2, pindel, varscan2
- MYCN | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1398902296, COSV99808048; called by muse, mutect2, varscan2
- MYO16 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291880607, COSV51798056; called by muse, mutect2, varscan2
- MYO1G | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763979006, COSV51854473; called by muse, mutect2, varscan2
- MYO5A | c.3532C>T p.R1178C | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs767451086, COSV62560909; called by muse, mutect2, varscan2
- MYO7B | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769391741, COSV67348010; called by muse, mutect2, varscan2
- MYOM1 | c.4949A>G p.N1650S | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99865231; called by muse, mutect2, varscan2
- MYT1 | c.2035C>T p.R679* | Nonsense Mutation (SNP) | VAF 35/225 reads (16%) | catalogued as rs1178710763, COSV60506783; called by muse, mutect2, varscan2
- MYT1L | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1393540875, COSV67702787; called by muse, mutect2, varscan2
- MZF1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs777893427, COSV53041753; called by muse, mutect2, varscan2
- NAPA | c.619_621del p.F207del | In Frame Del (DEL) | VAF 24/195 reads (12%) | catalogued as rs771568362; called by pindel, varscan2
- NAT10 | c.3027_3029del p.K1009del | In Frame Del (DEL) | VAF 26/134 reads (19%) | catalogued as rs772698051; called by pindel, varscan2
- NBEAL2 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV52758785; called by muse, mutect2, varscan2
- NCAM1 | c.1874G>T p.G625V (on ENST00000316851 / NM_181351.5; = p.G615V on NM_000615.7) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57517790; called by muse, mutect2, varscan2
- NCKAP5 | c.3340C>T p.Q1114* | Nonsense Mutation (SNP) | VAF 24/418 reads (6%) | catalogued as COSV100490041; called by muse, mutect2
- NCKAP5 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 29/434 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV100490043; called by muse, mutect2
- NCMAP | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 117/680 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV65556743; called by muse, mutect2, varscan2
- NCOA3 | c.3816_3818del p.Q1276del (on ENST00000371998 / NM_181659.3; = p.Q1272del on NM_006534.4) | In Frame Del (DEL) | VAF 18/120 reads (15%) | catalogued as rs772979098; called by pindel, varscan2
- NCOR2 | c.7360G>A p.A2454T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.567); catalogued as rs1412887711, COSV62299070; called by muse, mutect2, varscan2
- NDUFB5 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52020467; called by muse, mutect2, varscan2
- NDUFC1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 185/489 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs781664915, COSV55499518; called by muse, mutect2, varscan2
- NDUFS7 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.13); catalogued as rs778260862, COSV52039490; called by muse, mutect2, varscan2
- NEDD4 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV59062226; called by muse, varscan2
- NEFL | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55336242; called by muse, mutect2, varscan2
- NEMF | c.2710A>G p.N904D | Missense Mutation (SNP) | VAF 139/767 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV53592069; called by muse, mutect2, varscan2
- NFASC | c.814G>A p.G272R (on ENST00000339876 / NM_001378329.1; = p.G283R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58367006; called by muse, mutect2, varscan2
- NFATC3 | c.2435A>G p.N812S | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.97); catalogued as rs200413040; called by muse, mutect2, varscan2
- NFXL1 | c.2036G>T p.C679F | Missense Mutation (SNP) | VAF 49/482 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61199269; called by muse, mutect2, varscan2
- NINL | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748131161, COSV99624566; called by muse, mutect2, varscan2
- NISCH | c.3089G>A p.G1030D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1045853851, COSV61900439; called by muse, mutect2, varscan2
- NKX2-1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV61388873, COSV61389072; called by muse, varscan2
- NKX2-3 | c.306C>A p.S102R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV60728707, COSV60729368; called by muse, mutect2, varscan2
- NLRC5 | c.4070+1G>A p.X1357_splice | Splice Site (SNP) | VAF 6/96 reads (6%) | catalogued as rs969948546, COSV52649388, COSV52656976; called by muse, mutect2
- NLRP1 | c.3719G>A p.R1240H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs199948263; called by muse, mutect2
- NLRP14 | c.569del p.T190Kfs*4 | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | catalogued as COSV55067798; called by mutect2, pindel, varscan2
- NLRP7 | c.2584G>A p.G862R (on ENST00000340844 / NM_206828.3; = p.G834R on NM_139176.3) | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1335629453, COSV60175616; called by muse, mutect2, varscan2
- NLRP8 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV52588579; called by muse, mutect2, varscan2
- NLRP9 | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs746998723, COSV60463943; called by muse, mutect2, varscan2
- NMUR1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as rs373654111, COSV59404407; called by muse, mutect2, varscan2
- NMUR2 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV54919950; called by muse, mutect2, varscan2
- NOTCH4 | c.1046dup p.T350Hfs*4 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs766348245; called by mutect2, varscan2
- NPPA | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs768114654, COSV56740587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1D2 | c.1518T>A p.F506L | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56992198; called by muse, mutect2, varscan2
- NRCAM | c.1032_1033insT p.A345Cfs*12 (on ENST00000379028 / NM_001371124.1; = p.A339Cfs*12 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 51/477 reads (11%) | catalogued as COSV61039917; called by mutect2, pindel*
- NRG3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.15); catalogued as rs1351683889, COSV64568610; called by muse, mutect2, varscan2
- NRP1 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs760427841, COSV55160346; called by muse, mutect2, varscan2
- NSMCE1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs753831018, COSV53729917; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 80/437 reads (18%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTN3 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs141027585; called by muse, mutect2, varscan2
- NUAK1 | c.1507del p.S503Pfs*10 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as COSV54604031; called by pindel, varscan2
- NUP205 | c.4805T>C p.M1602T | Missense Mutation (SNP) | VAF 73/553 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs775517884, COSV53660258; called by muse, mutect2, varscan2
- NYNRIN | c.5141C>T p.T1714M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs367836472, COSV101230495; called by muse, mutect2, varscan2
- OBSCN | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as rs750877628, COSV52781386; called by muse, mutect2, varscan2
- OBSCN | c.5383G>A p.A1795T | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.16); catalogued as rs745536999, COSV52772135; called by muse, mutect2, varscan2
- OLFML2A | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775121644, COSV56583722; called by muse, mutect2, varscan2
- OR10H3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 70/637 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100008297; called by muse, mutect2, varscan2
- OR10K1 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 96/523 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV56872294, COSV56872710; called by muse, mutect2, varscan2
- OR14K1 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 109/460 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV99314960; called by muse, mutect2, varscan2
- OR1J2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 291/483 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58944458; called by muse, mutect2, varscan2
- OR1M1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs779435247, COSV70036970; called by muse, mutect2, varscan2
- OR2A14 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 99/754 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1171883711, COSV68718238; called by muse, mutect2, varscan2
- OR2C1 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59240456; called by muse, mutect2, varscan2
- OR2M5 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 96/645 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV63546401; called by muse, mutect2, varscan2
- OR2T35 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100442155; called by muse, varscan2
- OR4A47 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV71445012; called by muse, mutect2, varscan2
- OR4K15 | c.319G>T p.A107S (on ENST00000305051; = p.A83S on NM_001005486.1) | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100520965; called by muse, mutect2, varscan2
- OR4N2 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60051888; called by muse, mutect2, varscan2
- OR4S1 | c.630del p.F210Lfs*12 | Frame Shift Del (DEL) | VAF 112/514 reads (22%) | catalogued as COSV60678778; called by mutect2, varscan2
- OR51S1 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100437581, COSV59058389; called by muse, mutect2, varscan2
- OR5K3 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 49/396 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV67350171; called by muse, mutect2, varscan2
- OR5L2 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65723654, COSV65724497; called by muse, mutect2, varscan2
- OR7A17 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs964223126, COSV59414366; called by muse, mutect2, varscan2
- OSBPL10 | c.2186G>T p.R729L | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101158920; called by muse, mutect2
- OTULIN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240295700, COSV52504957; called by muse, mutect2, varscan2
- P2RX1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.16); catalogued as COSV99844541; called by muse, mutect2
- PANK1 | c.1114C>A p.L372I (on ENST00000307534 / NM_148977.2; = p.L147I on NM_138316.4) | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.691); catalogued as COSV56808514; called by muse, mutect2
- PAPOLB | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs759171720, COSV68201331; called by muse, varscan2
- PBX3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs1280344617, COSV60731536; called by muse, mutect2, varscan2
- PCDH10 | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52093046, COSV99992967; called by muse, mutect2, varscan2
- PCDH10 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs571561006, COSV52095799; called by muse, mutect2, varscan2
- PCDH11X | c.2387C>A p.P796Q | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100007748, COSV53471475; called by muse, mutect2, varscan2
- PCDH12 | c.611G>T p.R204M | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99185783; called by muse, mutect2
- PCDH15 | c.1582G>T p.V528F | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57323198; called by muse, mutect2
- PCDHA4 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as rs372115820; called by muse, mutect2, varscan2
- PCDHA7 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65344623; called by muse, mutect2, varscan2
- PCDHA7 | c.2246C>A p.S749* | Nonsense Mutation (SNP) | VAF 111/363 reads (31%) | catalogued as COSV100970429; called by muse, mutect2, varscan2
- PCDHGA3 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs200905776, COSV53961652; called by muse, mutect2, varscan2
- PCDHGA7 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 10/179 reads (6%) | catalogued as COSV99530699; called by muse, mutect2
- PCDHGB6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1477022032, COSV53961691; called by muse, mutect2, varscan2
- PCDHGC3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99338062; called by muse, mutect2, varscan2
- PCSK7 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs746646858, COSV58007841; called by muse, mutect2, varscan2
- PDGFD | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 78/566 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs754710218, COSV56380261; called by muse, mutect2, varscan2
- PDHA2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs774276941, COSV99756471; called by muse, mutect2
- PER1 | c.1675C>A p.Q559K | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.824); catalogued as COSV100424256; called by muse, mutect2, varscan2
- PFKP | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765385843, COSV66898508; called by muse, mutect2, varscan2
- PHC2 | c.828del p.A277Qfs*7 | Frame Shift Del (DEL) | VAF 46/265 reads (17%) | catalogued as COSV57104567; called by mutect2, pindel, varscan2
- PHKA1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); catalogued as COSV59806619; called by muse, mutect2, varscan2
- PHKG2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373732367, COSV60312294, COSV60313013; called by muse, mutect2, varscan2
- PHTF1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766585356, COSV54732703; called by muse, mutect2, varscan2
- PIAS4 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1442089986, COSV53679429; called by muse, mutect2
- PIAS4 | c.1464C>G p.D488E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.014); catalogued as COSV99518629; called by mutect2, varscan2
- PIKFYVE | c.2657del p.N886Tfs*7 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | catalogued as COSV52236390; called by mutect2, pindel, varscan2
- PIP5K1C | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs763799116, COSV58952873; called by muse, mutect2, varscan2
- PKD2L2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV51798361; called by muse, mutect2, varscan2
- PKD2L2 | c.1449+1G>A p.X483_splice | Splice Site (SNP) | VAF 27/412 reads (7%) | catalogued as COSV99295986; called by muse, mutect2
- PKP3 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779818959, COSV58987421; called by muse, mutect2, varscan2
- PLA2G6 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs772176591, COSV100140212, COSV59270870; called by muse, mutect2, varscan2
- PLEKHA2 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220715664, COSV56759677; called by muse, mutect2, varscan2
- PLEKHO2 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60261714, COSV60262185; called by muse, mutect2, varscan2
- PLIN4 | c.3002del p.G1001Afs*9 (on ENST00000301286; = p.G1016Afs*9 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs749737930; called by mutect2, pindel, varscan2
- PLVAP | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs199706929, COSV53085595; called by muse, mutect2, varscan2
- PNLIPRP2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs367948143, COSV53944240; called by muse, mutect2, varscan2
- PNPLA7 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs201477042, COSV53000009; called by muse, mutect2, varscan2
- POLRMT | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV73933290, COSV73933754; called by muse, mutect2, varscan2
- POMT2 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99836178; called by muse, mutect2, varscan2
- PPP1R12C | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1396504637, COSV52382828; called by muse, mutect2, varscan2
- PPP3CA | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59924500; called by muse, mutect2, varscan2
- PPRC1 | c.2425A>G p.R809G | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV53385866; called by muse, mutect2, varscan2
- PRKDC | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778630373, COSV100041000, COSV58054152; called by muse, mutect2, varscan2
- PROM2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs553459907, COSV58296835; called by mutect2, varscan2
- PROS1 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62398664; called by muse, mutect2, varscan2
- PRPF8 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1242961736, COSV100517137; called by muse, mutect2, varscan2
- PRR19 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs1435358717, COSV56625624; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1055T>C p.L352P (on ENST00000352766; = p.L273P on NM_181334.5) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV61234076; called by muse, mutect2, varscan2
- PRRC2B | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs1199044980, COSV61933531; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS54 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367701903; called by muse, mutect2, varscan2
- PRXL2A | c.218del p.N73Mfs*4 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | catalogued as COSV64690809; called by mutect2, pindel, varscan2
- PSKH1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.141); catalogued as rs747466620, COSV52122842; called by muse, mutect2, varscan2
- PTBP1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV62460357; called by muse, mutect2, varscan2
- PTDSS2 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755322933, COSV57278467; called by muse, mutect2, varscan2
- PTK2 | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs371607821; called by muse, mutect2, varscan2
- PTPRF | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs752774736, COSV100740590; called by muse, mutect2, varscan2
- PTPRR | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.749); catalogued as rs144147611; called by muse, mutect2, varscan2
- PTPRT | c.1916C>A p.A639E | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.881); catalogued as COSV61986148, COSV61998479; called by muse, mutect2, varscan2
- PUF60 | c.493G>A p.V165I (on ENST00000526683 / NM_001362896.2; = p.V148I on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs756023794, COSV57587972; called by muse, mutect2, varscan2
- PXDNL | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV62488866; called by muse, mutect2, varscan2
- PXN | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748821995, COSV57219175; called by muse, mutect2, varscan2
- PYGB | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs200843501; called by muse, mutect2, varscan2
- RAB10 | c.519+2T>C p.X173_splice | Splice Site (SNP) | VAF 60/233 reads (26%) | catalogued as COSV99265722; called by muse, mutect2, varscan2
- RAB14 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs771312021, COSV53045249; called by muse, varscan2
- RAB3B | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749093105, COSV65434345; called by muse, mutect2, varscan2
- RADIL | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs1420430280, COSV68201302; called by muse, mutect2, varscan2
- RAF1 | c.1420A>T p.I474L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV50105299; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 62/438 reads (14%) | catalogued as rs770990761; called by mutect2, varscan2
- RBM46 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 61/358 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs372380427; called by muse, mutect2, varscan2
- RCOR1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.793); catalogued as COSV99217188; called by muse, mutect2
- RFFL | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 66/287 reads (23%) | catalogued as COSV52071991; called by muse, mutect2, varscan2
- RFTN1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs748372599, COSV61918329; called by muse, mutect2, varscan2
- RGS14 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs374571122; called by muse, mutect2, varscan2
- RGS2 | c.190dup p.S64Kfs*12 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs775439827; called by mutect2, varscan2
- RHPN1 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149047880; called by muse, mutect2, varscan2
- RHPN1 | c.1879A>T p.T627S | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100000447; called by muse, mutect2, varscan2
- RIMBP2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142259939, COSV55474654; called by muse, mutect2, varscan2
- RINL | c.1415C>T p.T472M (on ENST00000591812 / NM_001195833.2; = p.T358M on NM_198445.4) | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV61573905; called by muse, mutect2, varscan2
- RIPK1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs376914574; called by muse, mutect2, varscan2
- RNF112 | c.1186G>C p.A396P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV71327059; called by muse, mutect2, varscan2
- RNF114 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775076155, COSV54869517; called by muse, mutect2, varscan2
- RNF151 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs537604935, COSV100364301; called by muse, mutect2, varscan2
- RNF167 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775675214, COSV52591150; called by muse, mutect2, varscan2
- RNPS1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.964); catalogued as rs745449452, COSV100066479; called by muse, mutect2
- ROBO1 | c.4466C>T p.A1489V | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.395); catalogued as COSV71395161; called by muse, mutect2
- ROR2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1208561867, COSV65216898; called by muse, mutect2, varscan2
- RP1 | c.3332C>A p.S1111* | Nonsense Mutation (SNP) | VAF 162/386 reads (42%) | catalogued as COSV55118244, COSV55125912; called by muse, mutect2, varscan2
- RPL13A | c.18C>T p.V6= | Splice Region (SNP) | VAF 22/381 reads (6%) | catalogued as COSV99201273; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS15A | c.133+1G>A p.X45_splice | Splice Site (SNP) | VAF 34/315 reads (11%) | catalogued as COSV100435772; called by muse, mutect2, varscan2
- RPS6KA4 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV53707425; called by muse, mutect2, varscan2
- RPUSD1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50100813; called by muse, mutect2, varscan2
- RRBP1 | c.2923G>A p.V975I (on ENST00000377813 / NM_001365613.2; = p.V542I on NM_004587.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs755236092, COSV55701346; called by muse, mutect2, varscan2
- RTN4IP1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764831004, COSV64805529; called by muse, varscan2
- RYR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs551099887, COSV63685496; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SALL3 | c.1214C>A p.S405* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV73305879, COSV73306109; called by muse, mutect2, varscan2
- SCARB2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV53668945; called by muse, mutect2, varscan2
- SCG3 | c.136-1G>T p.X46_splice | Splice Site (SNP) | VAF 185/474 reads (39%) | catalogued as COSV55021566; called by muse, mutect2, varscan2
- SCN10A | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101479246; called by muse, mutect2
- SCN4A | c.4084C>A p.L1362I | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV71127194; called by muse, mutect2, varscan2
- SCPEP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV99227690; called by muse, mutect2, varscan2
- SCRN3 | c.389T>G p.I130S | Missense Mutation (SNP) | VAF 176/430 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55808369; called by muse, mutect2, varscan2
- SEC14L5 | c.1863dup p.S622Qfs*31 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | catalogued as rs764657044; called by mutect2, varscan2
- SEC16A | c.3821G>A p.R1274H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs772546770, COSV51529560; called by muse, mutect2, varscan2
- SECTM1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53939603; called by muse, mutect2, varscan2
- SELP | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs749608555, COSV55247973; called by muse, mutect2, varscan2
- SELPLG | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs780303589, COSV57313069; called by muse, mutect2, varscan2
- SEMA3D | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 199/334 reads (60%) | catalogued as COSV52395019; called by muse, mutect2, varscan2
- SEMA5A | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs200629661, COSV101227086; called by muse, varscan2
- SERPINC1 | c.930C>G p.D310E | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV62929618; called by muse, mutect2, varscan2
- SERPINE3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV68545338; called by muse, mutect2, varscan2
- SEZ6L | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.616); catalogued as rs142863810, COSV50658559; called by muse, mutect2, varscan2
- SEZ6L2 | c.829G>A p.G277S (on ENST00000308713 / NM_001114099.3; = p.G207S on NM_012410.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs199665116, COSV58099998; called by muse, mutect2, varscan2
- SGIP1 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99390485; called by muse, mutect2, varscan2
- SGO2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs779103988, COSV63414510; called by muse, mutect2, varscan2
- SH2B3 | c.1038del p.L347Cfs*26 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs892433462; called by mutect2, pindel, varscan2
- SH3BP2 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.288); catalogued as COSV62554362; called by muse, mutect2, varscan2
- SH3PXD2B | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1378037423, COSV61124899; called by muse, mutect2, varscan2
- SH3RF1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs751242917, COSV52918788; called by muse, mutect2, varscan2
- SH3TC2 | c.2279G>A p.C760Y | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1383028898, COSV60464024; called by muse, mutect2, varscan2
- SHH | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 267/426 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095859, CM126228, CM126229, COSV51918995; called by muse, mutect2, varscan2
- SIGLEC12 | c.1205C>T p.A402V (on ENST00000291707 / NM_053003.4; = p.A284V on NM_033329.2) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.124); catalogued as COSV52462017; called by muse, mutect2, varscan2
- SIGLEC6 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs759524109, COSV58432506, COSV58433426; called by muse, mutect2, varscan2
- SIGLEC8 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.943); catalogued as COSV58474144, COSV58475788; called by muse, mutect2, varscan2
- SIM1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 53/295 reads (18%) | catalogued as COSV53492971; called by muse, mutect2, varscan2
- SLC10A6 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.095); catalogued as COSV56721852; called by muse, mutect2, varscan2
- SLC13A4 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775816451, COSV62461322; called by muse, mutect2, varscan2
- SLC17A6 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV54134234, COSV54139499; called by muse, mutect2, varscan2
- SLC17A7 | c.1655G>T p.R552M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as COSV55548091; called by muse, mutect2, varscan2
- SLC24A1 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV56052126; called by muse, varscan2
- SLC25A11 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV52591138; called by muse, mutect2, varscan2
- SLC27A1 | c.695T>C p.L232S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs745369666, COSV99392988; called by mutect2, varscan2
- SLC27A2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51062527; called by muse, mutect2
- SLC29A2 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60803399; called by muse, mutect2, varscan2
- SLC4A7 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs753444993, COSV55398089; called by muse, mutect2, varscan2
- SLC5A10 | c.1747C>A p.L583I (on ENST00000395645 / NM_001042450.4; = p.L599I on NM_152351.5) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV52413573; called by muse, mutect2, varscan2
- SLC7A4 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs753034553, COSV60384271; called by muse, mutect2, varscan2
- SLC9A5 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as rs756005398, COSV55362449; called by muse, mutect2, varscan2
- SLITRK2 | c.181dup p.Q61Pfs*35 | Frame Shift Ins (INS) | VAF 38/108 reads (35%) | catalogued as rs781792891; called by mutect2, varscan2
- SMAD9 | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63205115, COSV63205817; called by muse, mutect2, varscan2
- SMC1A | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 172/404 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV59129620; called by muse, mutect2, varscan2
- SMC5 | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV63192163; called by muse, mutect2, varscan2
- SMYD2 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 28/231 reads (12%) | catalogued as COSV65291028; called by muse, mutect2, varscan2
- SNAP47 | c.1002G>T p.E334D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV59917293, COSV59918168; called by muse, mutect2, varscan2
- SND1 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 78/711 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs143989011; called by muse, mutect2, varscan2
- SNRPN | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV57595101, COSV57597151; called by muse, mutect2, varscan2
- SNX11 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775844175, COSV63658589; called by muse, mutect2, varscan2
- SOGA3 | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV64106868; called by muse, mutect2, varscan2
- SON | c.7123G>A p.A2375T | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99276838; called by muse, mutect2, varscan2
- SORCS3 | c.2421G>T p.E807D | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100863389, COSV63793232; called by muse, mutect2, varscan2
- SOX3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 60/72 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV65168303; called by muse, mutect2, varscan2
- SOX7 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs746671600, COSV58731016; called by muse, mutect2, varscan2
- SPANXN4 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.618); catalogued as COSV65141436; called by muse, mutect2, varscan2
- SPATA31E1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as rs1254860155, COSV57792281; called by muse, mutect2, varscan2
- SPATS1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774223747, COSV55823534; called by muse, mutect2, varscan2
- SPDEF | c.572T>C p.F191S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65001033; called by muse, mutect2, varscan2
- SPEG | c.8026C>T p.R2676* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as rs377619914; called by muse, varscan2
- SPICE1 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 78/518 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99870860; called by muse, mutect2, varscan2
- SPPL2B | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs1245788387, COSV101194580; called by muse, mutect2, varscan2
- SPPL2B | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs529252797, COSV101476098; called by muse, mutect2
- SPTBN2 | c.4990C>T p.R1664W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394635759, COSV100018190; called by muse, mutect2, varscan2
- SPTBN4 | c.7685G>A p.R2562H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.707); catalogued as rs765129909, COSV99398849; called by muse, mutect2, varscan2
- SPX | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.286); catalogued as rs201207493, COSV57020941, COSV57021716; called by muse, mutect2, varscan2
- SRRM2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs776845355, COSV57074137; called by muse, mutect2, varscan2
- SSH1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58457291; called by muse, mutect2
- ST6GALNAC2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | PolyPhen benign (0.063); catalogued as rs776553153, COSV56571534; called by muse, mutect2, varscan2
- STAC3 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60414133; called by muse, mutect2, varscan2
- STAT2 | c.2446A>G p.M816V | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV57336098; called by muse, mutect2, varscan2
- STAT5A | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61806937; called by muse, mutect2, varscan2
- STAT5B | c.1749dup p.H584Tfs*8 | Frame Shift Ins (INS) | VAF 30/165 reads (18%) | catalogued as rs1202978138; called by mutect2, varscan2
- STAT6 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs775447215, COSV100273087, COSV55668786; called by muse, mutect2, varscan2
- STEAP3 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61529356; called by muse, varscan2
- STK3 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69223957; called by muse, mutect2, varscan2
- STK35 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99852581; called by muse, mutect2
- STOX2 | c.1926G>T p.Q642H | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV57852799; called by muse, mutect2, varscan2
- SULF1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 105/510 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs762343638, COSV52676968; called by muse, mutect2, varscan2
- SVEP1 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100237179; called by muse, mutect2, varscan2
- SYMPK | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 22/152 reads (14%) | catalogued as rs897613793, COSV55612338, COSV99842250; called by muse, mutect2, varscan2
- SYNE1 | c.23623G>A p.A7875T (on ENST00000367255 / NM_182961.4; = p.A7804T on NM_033071.3) | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54999978; called by muse, mutect2, varscan2
- SYNE3 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs182425490, COSV62079943; called by muse, mutect2, varscan2
- TACR3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59202383; called by muse, mutect2, varscan2
- TAF1L | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 287/530 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258011; called by muse, mutect2, varscan2
- TAF6L | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs200288910, COSV53669035; called by muse, mutect2, varscan2
- TAF7 | c.250del p.T84Lfs*57 | Frame Shift Del (DEL) | VAF 59/250 reads (24%) | catalogued as rs761173015; called by mutect2, pindel, varscan2
- TAOK3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs753748348, COSV66826120; called by muse, mutect2, varscan2
- TARBP1 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs750889517, COSV50186779; called by muse, mutect2, varscan2
- TAS1R1 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV59839965, COSV59840152; called by muse, mutect2, varscan2
- TAS2R43 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs773874004, COSV67856680; called by muse, varscan2
- TAT | c.236-2del p.X79_splice | Splice Site (DEL) | VAF 64/265 reads (24%) | catalogued as COSV63533168; called by mutect2, varscan2
- TBL2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs141002736; called by muse, mutect2, varscan2
- TBX1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1342897153, COSV60353891; called by muse, mutect2, varscan2
- TBX2 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs866915098, COSV99538607; called by muse, mutect2, varscan2
- TBX4 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1481280349, COSV53607771; called by muse, mutect2, varscan2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 40/163 reads (25%) | catalogued as rs778855667; called by mutect2, pindel, varscan2
- TCF7L2 | c.1463G>A p.R488H (on ENST00000355995 / NM_001367943.1; = p.R465H on NM_030756.5) | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV53338022, COSV53349437; called by muse, mutect2, varscan2
- TCTEX1D4 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59500034; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM2 | c.5846G>A p.R1949H (on ENST00000518659 / NM_001122679.2; = p.R1710H on NM_001080428.3) | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs201501970; called by muse, mutect2, varscan2
- TEPSIN | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747438452, COSV56143154; called by muse, mutect2, varscan2
- TEX264 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs201059799, COSV100392479; called by muse, mutect2, varscan2
- TGFBR2 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 58/231 reads (25%) | catalogued as COSV55450963; called by muse, mutect2, varscan2
- THSD7A | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 650/1033 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs750574911, COSV70265835; called by muse, mutect2, varscan2
- TIAM1 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99732814; called by muse, mutect2, varscan2
- TIGD2 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV57647937; called by muse, mutect2, varscan2
- TLE4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746243498, COSV54633119; called by muse, mutect2, varscan2
- TM6SF2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771340141, COSV66985352; called by muse, mutect2, varscan2
- TMCC2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs776296421, COSV100319160; called by muse, varscan2
- TMED2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99147717; called by muse, mutect2, varscan2
- TMEM108 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as COSV58873128; called by muse, mutect2, varscan2
- TMEM116 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | catalogued as COSV61392365; called by muse, mutect2
- TMEM132E | c.1136C>T p.A379V (on ENST00000321639; = p.A469V on NM_001304438.2) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100395933; called by muse, mutect2, varscan2
- TMEM161B | c.1447T>C p.Y483H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as rs748118522, COSV56931298; called by muse, mutect2, varscan2
- TMEM181 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs764560943, COSV65565516; called by muse, varscan2
- TMEM59L | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.557); catalogued as COSV53242433; called by muse, mutect2, varscan2
- TMEM63A | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs766612215, COSV100834265; called by muse, varscan2
- TMEM63B | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367749788; called by muse, mutect2, varscan2
- TMEM87A | c.504+1G>A p.X168_splice | Splice Site (SNP) | VAF 63/334 reads (19%) | catalogued as rs1566939940, COSV56197550; called by muse, varscan2
- TMEM9 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV66243905; called by muse, mutect2, varscan2
- TMTC1 | c.421C>T p.R141C (on ENST00000539277 / NM_001193451.2; = p.R33C on NM_175861.3) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756612885, COSV55483497; called by muse, varscan2
- TNFRSF18 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100148807; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV64101286; called by muse, mutect2, varscan2
- TNRC6B | c.3862C>T p.Q1288* (on ENST00000454349 / NM_001162501.2; = p.Q1178* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 73/196 reads (37%) | catalogued as COSV57297712; called by muse, mutect2, varscan2
- TNS3 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs760674078, COSV60792133; called by muse, mutect2, varscan2
- TNS3 | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | catalogued as COSV100234738; called by muse, mutect2, varscan2
- TOGARAM1 | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV61888339; called by muse, mutect2, varscan2
- TP73 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769809364, COSV60702409; called by muse, mutect2, varscan2
- TRAK2 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100216628; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 37/255 reads (15%) | catalogued as rs770561785; called by mutect2, varscan2
- TRAPPC9 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs779077167, COSV101226676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIB3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs199753662, COSV53930596; called by muse, mutect2, varscan2
- TRIL | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs928892673, COSV100538721; called by muse, varscan2
- TRIL | c.2333A>G p.D778G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100538723; called by muse, varscan2
- TRIM9 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as rs1407520404, COSV53618193; called by muse, mutect2, varscan2
- TRIOBP | c.3775G>A p.G1259R | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs755555403, COSV100730592; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT12 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1050325334, COSV60777186; called by muse, mutect2, varscan2
- TROAP | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs1394485672, COSV99226661; called by muse, mutect2, varscan2
- TRPM8 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.825); catalogued as rs200884995, COSV100223593, COSV61225033; called by muse, mutect2, varscan2
- TSC2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1015282988, COSV54593115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC22D4 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773665153, COSV55724308; called by muse, mutect2, varscan2
- TSHZ1 | c.2498G>A p.R833Q (on ENST00000580243 / NM_001308210.2; = p.R788Q on NM_005786.6) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.92); catalogued as rs781707604, COSV59010697; called by muse, mutect2, varscan2
- TTC23 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs1336499540, COSV100018370, COSV50445003; called by muse, mutect2, varscan2
- TTC37 | c.4594G>A p.A1532T | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100706362; called by muse, mutect2, varscan2
- TTC39C | c.456G>T p.L152F (on ENST00000317571 / NM_001135993.2; = p.L91F on NM_153211.4) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV58217886; called by muse, mutect2, varscan2
- TTLL9 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs776174245, COSV100206287; called by muse, mutect2, varscan2
- TTN | c.92707G>T p.D30903Y (on ENST00000591111; = p.D23479Y on NM_003319.4) | Missense Mutation (SNP) | VAF 69/374 reads (18%) | PolyPhen probably damaging (0.944); catalogued as COSV60106794; called by muse, mutect2, varscan2
- TTN | c.88507C>T p.R29503W (on ENST00000591111; = p.R22079W on NM_003319.4) | Missense Mutation (SNP) | VAF 71/232 reads (31%) | PolyPhen probably damaging (0.999); catalogued as rs770088691, COSV60111692; called by muse, mutect2, varscan2
- TTN | c.41974G>T p.G13992W (on ENST00000591111; = p.G6568W on NM_003319.4) | Missense Mutation (SNP) | VAF 122/292 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV60106818; called by muse, mutect2, varscan2
- TUBB2A | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 123/307 reads (40%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.931); catalogued as COSV61319113; called by muse, mutect2, varscan2
476 further variants in this file (170 protein-altering or splice-affecting, 282 silent, 24 other) are not listed here.
